TCGA case TCGA-C5-A0TN — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/14c65927-b9dd-4ef6-9917-db7bc431ff2f

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 21 years; Vital status: Dead; Days to death: 348 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, keratinizing, NOS (the primary disease): ICD-O-3 morphology code: 8071/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 21.2 years (7,760 days); Year of diagnosis: 1997; Method of diagnosis: Surgical Resection; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: MX; FIGO stage: Stage IB2; FIGO staging edition year: 1995; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 10; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 47 days; Days to treatment end: 57 days; Treatment dose: 1,440 cGy; Course number: 1; Number of fractions: 4; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 67 days; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 98 days; Days to treatment end: 111 days; Treatment dose: 360 cGy; Course number: 2; Number of fractions: 2; Treatment anatomic sites: Locoregional Site.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, keratinizing, NOS), site: Pelvis, NOS. Age at diagnosis: 21.4 years (7,822 days); Days to diagnosis: 62 days; Prior treatment: Yes.

Follow-up (8 entries)
- Day -2 (preoperative): Days to imaging: -2 days; Imaging type: MRI; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day -2 (preoperative): Days to imaging: -2 days; Imaging type: MRI; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day -2 (preoperative): Days to imaging: -2 days; Imaging type: MRI; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day -2 (preoperative): Days to imaging: -2 days; Imaging type: MRI; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day -2 (preoperative): Days to imaging: -2 days; Imaging type: MRI; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day -2 (preoperative): Days to imaging: -2 days; Imaging type: MRI; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 62 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvis, NOS; Days to progression: 62 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 348 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.
- Timepoint category: Initial Diagnosis; Weight: 55 kg.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 3; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A0TN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 170 mg.
  Slide TCGA-C5-A0TN-01A-02-MSB: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 20.
  Slide TCGA-C5-A0TN-01A-02-BSB: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 20.
- Sample TCGA-C5-A0TN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A0TN-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 1; Pregnancies count induced abortion: 3; Total pregnancy count: 4; Tobacco smoking history indicator: 1; Tumor response: Progression; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: surgery; Margins involved hysterectomy: Microscopic parametrial involvement; Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Diagnostic mri result outcomes: Lymph nodes supraclavicular: Bladder Absent; Lymph nodes supraclavicular: Extra-Pelvic Metastatic Disease Absent; Lymph nodes supraclavicular: Parametrium Absent; Lymph nodes supraclavicular: Paraaortic Nodes Absent; Lymph nodes supraclavicular: Pelvic Nodes Absent; Lymph nodes supraclavicular: Supraclavicular Absent.
- Follow-up form: Tumor status: With tumor; Cause of death: Cervical Cancer; Radiation adjuvant indicator: Yes; Radiation therapy xrt type: External beam radiation; New tumor event type: Distant Metastasis; New tumor event site other: Pelvis/Liver; New tumor event surgery: CT; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form, Radiation supplemental: Radiation therapy status: Treatment not completed.
- Drug treatment: Regimen number: 1; Therapy regimen: Progression.
- Drug treatment, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 348 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 348 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 62 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A0TN-01A-21D-A14V-01): tumor purity 0.89, ploidy 1.81, whole-genome doublings 0.
